Somatic mutation profile of tumor specimen TCGA-BK-A0CA-01B (aliquot TCGA-BK-A0CA-01B-02D-A272-09) from TCGA case TCGA-BK-A0CA, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 61.3 years (22,378 days).
Specimen TCGA-BK-A0CA-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c58870a-f3a0-4fd6-88ff-c44a45c8b351.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BK-A0CA-10A (Blood Derived Normal), aliquot TCGA-BK-A0CA-10A-02D-A272-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e6de1ab-a813-4d67-b78a-1c63b671b17b

The open-access MAF lists 245 somatic variants for this specimen: 194 protein-altering or splice-affecting, 48 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 115, Frame Shift Del 49, Silent 48, Frame Shift Ins 10, Nonsense Mutation 7, In Frame Del 6, Splice Region 5, Intron 2, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASXL1 | c.1926_1927del p.G645Wfs*12 | Frame Shift Del (DEL) | VAF 13/84 reads (15%) | hotspot (GDC flag); called by pindel, varscan2
- ATP6V1B1 | c.1155del p.I386Sfs*10 | Frame Shift Del (DEL) | VAF 18/100 reads (18%) | catalogued as rs781969081; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by mutect2, varscan2
- PURA | c.812_814del p.F271del | In Frame Del (DEL) | VAF 4/28 reads (14%) | catalogued as rs587782991; ClinVar: pathogenic; called by mutect2, pindel
- TP53 | c.730G>T p.G244C | Missense Mutation (SNP) | VAF 28/104 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519989, CM144215, COSV52668392, COSV52676997, COSV52808251; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 8/78 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.573del p.F192Sfs*40 | Frame Shift Del (DEL) | VAF 10/29 reads (34%) | catalogued as rs1172142986; called by mutect2, varscan2
- ACAA1 | c.746G>A p.R249H | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs115896366; called by muse, mutect2, varscan2
- ADCY10 | c.1357G>A p.V453I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.987); catalogued as rs1256878119, COSV100897150; called by mutect2, varscan2
- ADGRE2 | c.2068G>T p.G690* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as COSV59693941; called by muse, mutect2, varscan2
- ADRA1D | c.730C>T p.R244C | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.849); catalogued as COSV65241622; called by muse, mutect2, varscan2
- ALDH1A3 | c.833C>T p.T278M | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs567004839, COSV60901605; called by mutect2, varscan2
- AP1G1 | c.916C>T p.R306* | Nonsense Mutation (SNP) | VAF 5/35 reads (14%) | catalogued as rs776081558; called by mutect2, varscan2
- AP2A1 | c.2413C>T p.L805= | Splice Region (SNP) | VAF 14/63 reads (22%) | catalogued as COSV100571078; called by muse, varscan2
- AP2A1 | c.2414T>C p.L805P | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.237); catalogued as COSV100571083; called by muse, varscan2
- ATR | c.3587G>A p.W1196* | Nonsense Mutation (SNP) | VAF 10/52 reads (19%) | catalogued as COSV63386417; called by muse, varscan2
- BCAM | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs746759389; called by muse, mutect2, varscan2
- BEST3 | c.1332del p.R445Gfs*40 | Frame Shift Del (DEL) | VAF 9/85 reads (11%) | catalogued as rs779566914, COSV58300788; called by mutect2, pindel
- BMP15 | c.163G>A p.E55K | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs868942078, COSV53139709; called by muse, mutect2, varscan2
- BRF2 | c.115del p.V39Sfs*15 | Frame Shift Del (DEL) | VAF 7/72 reads (10%) | catalogued as rs757254105; called by mutect2, pindel
- C12orf42 | c.1009del p.R337Afs*19 | Frame Shift Del (DEL) | VAF 26/110 reads (24%) | catalogued as rs771322722; called by mutect2, pindel, varscan2
- C4orf17 | c.253del p.S85Pfs*10 | Frame Shift Del (DEL) | VAF 9/74 reads (12%) | catalogued as rs201447915; called by mutect2, pindel, varscan2
- CCDC136 | c.614T>C p.M205T | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs959696462; called by muse, varscan2
- CCDC39 | c.2366C>T p.T789M | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.591); catalogued as rs747000468, COSV56485827, COSV99869095; called by muse, mutect2, varscan2
- CDC14A | c.375del p.Y126Ifs*64 | Frame Shift Del (DEL) | VAF 22/105 reads (21%) | catalogued as rs773911500; called by mutect2, varscan2
- CDH17 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.816); catalogued as rs745601353; called by muse, mutect2, varscan2
- CFAP126 | c.227del p.P76Lfs*4 | Frame Shift Del (DEL) | VAF 17/85 reads (20%) | catalogued as rs780823798; called by mutect2, pindel, varscan2
- CGN | c.172C>T p.Q58* | Nonsense Mutation (SNP) | VAF 7/42 reads (17%) | catalogued as rs1198230533; called by muse, mutect2, varscan2
- CHRNG | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 14/82 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); catalogued as rs777208622, COSV67315175, COSV67316165; called by muse, varscan2
- CLP1 | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 6/25 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.17); catalogued as rs1219375434, COSV57054434; called by muse, mutect2, varscan2
- CLVS2 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs769820536, COSV51562567; called by muse, mutect2, varscan2
- COL6A2 | c.1674G>A p.A558= | Splice Region (SNP) | VAF 19/98 reads (19%) | catalogued as rs144334894, COSV100153204; ClinVar: uncertain significance / likely benign; called by muse, mutect2, varscan2
- COL6A2 | c.2866A>G p.S956G | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.048); catalogued as rs760808874; called by muse, mutect2, varscan2
- CRYGA | c.476del p.G159Vfs*9 | Frame Shift Del (DEL) | VAF 12/64 reads (19%) | catalogued as rs762650691; called by mutect2, pindel, varscan2
- CS | c.685G>A p.A229T | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as COSV60831971; called by muse, mutect2, varscan2
- CSMD1 | c.3866G>A p.R1289Q (on ENST00000520002; = p.R1288Q on NM_033225.6) | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.99); catalogued as rs780978438, COSV59300261, COSV59344665; called by muse, mutect2, varscan2
- CSTF3 | c.1784G>A p.R595Q | Missense Mutation (SNP) | VAF 38/174 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.327); catalogued as COSV60610006, COSV60612736; called by muse, varscan2
- CYB5R2 | c.334G>A p.G112R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs962632087, COSV100207342, COSV55085060; called by muse, mutect2, varscan2
- EQTN | c.77-3del | Splice Region (DEL) | VAF 6/38 reads (16%) | catalogued as rs768793415; called by mutect2, varscan2
- ESRP1 | c.1535del p.N512Tfs*2 | Frame Shift Del (DEL) | VAF 24/74 reads (32%) | catalogued as rs775950025; called by mutect2, varscan2
- ESX1 | c.893C>T p.P298L | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.314); catalogued as rs782488534, COSV65424506; called by muse, mutect2, varscan2
- EXOSC10 | c.1del p.M1? | Frame Shift Del (DEL) | VAF 18/94 reads (19%) | catalogued as rs1295501255; called by mutect2, pindel, varscan2
- FUT3 | c.877G>A p.V293M | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54605447; called by muse, mutect2, varscan2
- GPR19 | c.1109del p.N370Tfs*59 | Frame Shift Del (DEL) | VAF 23/136 reads (17%) | catalogued as rs1416935976; called by mutect2, varscan2
- GTF3C2 | c.1057_1059del p.E353del | In Frame Del (DEL) | VAF 7/54 reads (13%) | catalogued as rs1558616827; called by pindel, varscan2
- HDGFL2 | c.677del p.K226Rfs*45 | Frame Shift Del (DEL) | VAF 30/143 reads (21%) | catalogued as rs1219916331, COSV56682191; called by mutect2, varscan2
- HEXIM2 | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated (0.45); PolyPhen benign (0.01); catalogued as COSV100218009; called by muse, mutect2, varscan2
- HLA-DRB5 | c.484C>T p.R162W | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.947); catalogued as rs758127925, COSV66612048; called by muse, mutect2, varscan2
- IFT140 | c.3383G>A p.R1128H | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as rs147661907; called by muse, mutect2, varscan2
- INTS1 | c.3335C>T p.A1112V | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs778381554; called by muse, mutect2, varscan2
- KMT2B | c.5730del p.R1911Dfs*23 | Frame Shift Del (DEL) | VAF 10/78 reads (13%) | catalogued as COSV55867385; called by mutect2, pindel
- KMT5C | c.1300G>A p.A434T | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.199); catalogued as rs368324629; called by mutect2, varscan2
- LRGUK | c.697C>G p.L233V | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV53641300; called by muse, mutect2, varscan2
- MCM7 | c.1082del p.G361Vfs*9 | Frame Shift Del (DEL) | VAF 7/46 reads (15%) | catalogued as rs1216888855; called by mutect2, pindel, varscan2
- MEGF8 | c.3384T>A p.S1128R (on ENST00000251268 / NM_001271938.2; = p.S1061R on NM_001410.3) | Missense Mutation (SNP) | VAF 59/193 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52073656; called by muse, mutect2, varscan2
- MME | c.594del p.V199Sfs*15 | Frame Shift Del (DEL) | VAF 8/43 reads (19%) | catalogued as rs1254522989, COSV64706032; called by mutect2, pindel, varscan2
- MYO1H | c.320T>G p.M107R | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.323); catalogued as COSV60442496; called by muse, mutect2, varscan2
- MYOF | c.2827G>A p.G943R | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs750634151, COSV63702213, COSV63704243; called by muse, mutect2, varscan2
- NTAN1 | c.890del p.N297Mfs*63 | Frame Shift Del (DEL) | VAF 32/127 reads (25%) | catalogued as rs753931847; called by mutect2, varscan2
- NUCB1 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.508); catalogued as rs1304159585, COSV99618045; called by muse, mutect2, varscan2
- NUP214 | c.681del p.V228Sfs*29 | Frame Shift Del (DEL) | VAF 11/82 reads (13%) | catalogued as rs771913112, COSV63912486; called by mutect2, varscan2
- OGFOD1 | c.1140dup p.E381Rfs*6 | Frame Shift Ins (INS) | VAF 3/20 reads (15%) | catalogued as rs1311827633; called by pindel, varscan2
- OR5B17 | c.125G>A p.G42E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.972); catalogued as COSV62159783; called by muse, mutect2, varscan2
- PCDHA3 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 17/206 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.801); catalogued as rs782257139, COSV65364473; called by muse, mutect2
- PCLO | c.3719del p.K1240Sfs*78 | Frame Shift Del (DEL) | VAF 30/179 reads (17%) | catalogued as COSV61638231; called by mutect2, pindel, varscan2
- PEPD | c.1438G>A p.A480T | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as rs1568442025; called by muse, mutect2, varscan2
- PFDN5 | c.286G>A p.A96T | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.017); catalogued as rs772527648; called by mutect2, varscan2
- PGAM1 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.149); catalogued as rs1279393492; called by muse, mutect2, varscan2
- PIF1 | c.956T>C p.L319P | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200489734, CM121472; called by muse, mutect2, varscan2
- PIK3CA | c.1345C>T p.P449S | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55932192, COSV55944790; called by muse, mutect2, varscan2
- PLAAT4 | c.483del p.A162Rfs*56 | Frame Shift Del (DEL) | VAF 10/66 reads (15%) | catalogued as rs745860467; called by mutect2, varscan2
- PNMA5 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.043); catalogued as rs782037514, COSV62625606; called by muse, mutect2, varscan2
- PPP2R5A | c.1351C>T p.R451C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779233052; called by muse, mutect2, varscan2
- PRDM10 | c.658G>A p.G220R | Missense Mutation (SNP) | VAF 6/71 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58799309; called by muse, mutect2
- PROKR1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.348); catalogued as COSV100375559, COSV58136445; called by muse, mutect2, varscan2
- PRRC2B | c.100G>A p.A34T | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs1212621247, COSV61933496; called by muse, mutect2, varscan2
- PRSS8 | c.124del p.Q42Kfs*64 | Frame Shift Del (DEL) | VAF 12/43 reads (28%) | catalogued as COSV99571515; called by mutect2, pindel, varscan2
- PYGM | c.443T>C p.M148T | Missense Mutation (SNP) | VAF 37/145 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99377500; called by muse, mutect2, varscan2
- RFX1 | c.2608G>A p.A870T | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.833); catalogued as COSV99586324; called by muse, mutect2, varscan2
- ROCK1 | c.3921del p.K1307Nfs*3 | Frame Shift Del (DEL) | VAF 8/56 reads (14%) | catalogued as rs752898741; called by mutect2, varscan2
- RTN3 | c.3089del p.K1030Rfs*67 (on ENST00000377819 / NM_001265589.2; = p.K234Rfs*67 on NM_006054.4) | Frame Shift Del (DEL) | VAF 8/28 reads (29%) | catalogued as rs747510098; called by mutect2, varscan2
- SEC14L5 | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.241); catalogued as rs373434753; called by muse, mutect2, varscan2
- SKAP2 | c.442G>C p.V148L | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.031); catalogued as COSV100591749; called by muse, mutect2, varscan2
- SLC25A13 | c.1406G>T p.S469I | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV55703115, COSV55708551; called by muse, mutect2, varscan2
- SLC26A1 | c.131T>C p.L44P | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs990505881; called by muse, varscan2
- SLCO4A1 | c.2072C>T p.P691L | Missense Mutation (SNP) | VAF 33/141 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as COSV53888954; called by muse, mutect2, varscan2
- SMAP1 | c.515del p.K172Rfs*48 (on ENST00000370455 / NM_001044305.3; = p.K145Rfs*48 on NM_021940.5) | Frame Shift Del (DEL) | VAF 13/53 reads (25%) | catalogued as rs763364024; called by mutect2, varscan2
- SMPDL3B | c.754C>T p.R252W | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs144852835; called by mutect2, varscan2
- SNAPC3 | c.996_998del p.D333del | In Frame Del (DEL) | VAF 8/36 reads (22%) | catalogued as rs1414999327; called by pindel, varscan2
- SNX29 | c.2316C>T p.F772= | Splice Region (SNP) | VAF 8/58 reads (14%) | catalogued as rs369501793; called by mutect2, varscan2
- SORCS1 | c.2938C>T p.R980C | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs377202317; called by muse, mutect2, varscan2
- SPG7 | c.1750G>A p.V584M (on ENST00000268704; = p.V591M on NM_003119.4) | Missense Mutation (SNP) | VAF 71/239 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.758); catalogued as rs199804717, COSV99245101; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- STEAP2 | c.680del p.F227Sfs*9 | Frame Shift Del (DEL) | VAF 6/23 reads (26%) | catalogued as rs754344704; called by mutect2, varscan2
- TCERG1 | c.2870del p.K957Rfs*17 | Frame Shift Del (DEL) | VAF 6/28 reads (21%) | catalogued as rs758822980; called by mutect2, varscan2
- TMEM175 | c.56del p.P19Qfs*33 | Frame Shift Del (DEL) | VAF 11/95 reads (12%) | catalogued as rs1438211639; called by mutect2, pindel, varscan2
- TOX | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 19/108 reads (18%) | catalogued as COSV100789271; called by muse, mutect2, varscan2
- TRANK1 | c.1762C>T p.R588W | Missense Mutation (SNP) | VAF 38/138 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.759); catalogued as rs1385227247; called by muse, mutect2, varscan2
- TRPA1 | c.2294C>T p.T765M | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.174); catalogued as rs74545891; called by muse, mutect2, varscan2
- TTN | c.99860A>T p.Y33287F (on ENST00000591111; = p.Y25863F on NM_003319.4) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | PolyPhen benign (0.067); catalogued as COSV59861737; called by muse, mutect2, varscan2
- TXLNA | c.784C>T p.R262W | Missense Mutation (SNP) | VAF 6/26 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1457498019; called by muse, mutect2
- UBAP1 | c.1177C>T p.R393W | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as rs767729778, COSV99903014; called by mutect2, varscan2
- UHRF1BP1 | c.3996del p.I1333Sfs*20 | Frame Shift Del (DEL) | VAF 13/99 reads (13%) | catalogued as COSV51954201; called by mutect2, pindel, varscan2
- UNC5D | c.983G>A p.R328Q | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54765601, COSV99772837; called by muse, varscan2
- USP9X | c.1252C>T p.R418C | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61065718; called by muse, mutect2, varscan2
- WNK2 | c.531G>C p.E177D | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as rs368882633; called by muse, mutect2, varscan2
- YTHDF1 | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 15/52 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs755737262; called by muse, mutect2, varscan2
- ZBTB8OS | c.71A>T p.N24I | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV59386292; called by muse, mutect2, varscan2
- ZFP36L2 | c.683del p.G228Afs*233 | Frame Shift Del (DEL) | VAF 8/48 reads (17%) | catalogued as COSV99144234; called by mutect2, pindel, varscan2
- ZHX1 | c.*2A>T | Splice Region (SNP) | VAF 21/88 reads (24%) | catalogued as COSV99933584; called by muse, mutect2, varscan2
- ZNF667 | c.500C>T p.T167I | Missense Mutation (SNP) | VAF 21/77 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.019); catalogued as rs754470431, COSV52634143; called by muse, mutect2, varscan2
- ZNF804A | c.815A>G p.E272G | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.769); catalogued as COSV56433533; called by muse, mutect2
- ZP1 | c.1768C>T p.P590S | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV53922900; called by muse, mutect2, varscan2
- AL031777.2 | c.227dup p.T77Dfs*24 | Frame Shift Ins (INS) | VAF 30/189 reads (16%) | called by mutect2, pindel, varscan2
- ALG10 | c.886del p.S296Hfs*23 | Frame Shift Del (DEL) | VAF 20/126 reads (16%) | called by mutect2, pindel, varscan2
- ANKRD9 | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- ANKS1B | c.400T>C p.C134R | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRD1 | c.2076dup p.R693Afs*177 (on ENST00000216267 / NM_001349940.1; = p.R693Afs*97 on NM_001304808.3) | Frame Shift Ins (INS) | VAF 29/111 reads (26%) | called by mutect2, pindel, varscan2
- BRD7 | c.1644G>T p.E548D | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- CCDC9B | c.25A>G p.S9G | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- CRNKL1 | c.1556C>T p.A519V | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.889); called by muse, mutect2, varscan2
- CSTF3 | c.1697C>A p.S566Y | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.652); called by muse, varscan2
- DARS1 | c.165del p.A56Lfs*23 | Frame Shift Del (DEL) | VAF 13/83 reads (16%) | called by mutect2, pindel, varscan2
- DDX49 | c.866C>T p.A289V | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by mutect2, varscan2
- DIAPH1 | c.3430_3431del p.M1144Vfs*51 | Frame Shift Del (DEL) | VAF 7/30 reads (23%) | called by pindel, varscan2
- DRP2 | c.2800A>G p.M934V | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.678); called by muse, mutect2, varscan2
- DST | c.7790A>G p.D2597G | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- FAH | c.356C>T p.A119V | Missense Mutation (SNP) | VAF 14/37 reads (38%) | SIFT tolerated (0.96); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- FAM98A | c.399del p.A134Lfs*13 | Frame Shift Del (DEL) | VAF 11/112 reads (10%) | called by mutect2, pindel, varscan2
- FBXL19 | c.743_745del p.L248del | In Frame Del (DEL) | VAF 8/40 reads (20%) | called by pindel, varscan2
- GAREM1 | c.529A>T p.I177F | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- GP2 | c.884C>A p.A295D (on ENST00000381362 / NM_001007240.3; = p.A292D on NM_001502.4) | Missense Mutation (SNP) | VAF 28/146 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HMGN1 | c.127-3_127-2del p.X43_splice | Splice Site (DEL) | VAF 30/141 reads (21%) | called by mutect2, pindel, varscan2
- IL3RA | c.980G>T p.R327M | Missense Mutation (SNP) | VAF 22/221 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- INTS8 | c.2686_2687del p.Q896Gfs*12 | Frame Shift Del (DEL) | VAF 11/101 reads (11%) | called by pindel, varscan2
- IWS1 | c.2404del p.S802Afs*7 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by mutect2, pindel, varscan2
- IWS1 | c.2004dup p.K669Qfs*6 | Frame Shift Ins (INS) | VAF 6/66 reads (9%) | called by mutect2, pindel
- KCNC3 | c.1693dup p.R565Pfs*14 | Frame Shift Ins (INS) | VAF 9/75 reads (12%) | called by mutect2, pindel, varscan2
- KLHDC2 | c.311A>G p.Y104C | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- KPNA1 | c.1051A>T p.K351* | Nonsense Mutation (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2, varscan2
- LAS1L | c.71A>T p.Y24F | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- LEPROT | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 32/164 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAG | c.803del p.P268Rfs*4 | Frame Shift Del (DEL) | VAF 6/38 reads (16%) | called by mutect2, pindel, varscan2
- MEGF8 | c.2404G>A p.A802T (on ENST00000251268 / NM_001271938.2; = p.A735T on NM_001410.3) | Missense Mutation (SNP) | VAF 37/190 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- MMP27 | c.1298-1G>T p.X433_splice | Splice Site (SNP) | VAF 18/58 reads (31%) | called by muse, mutect2, varscan2
- NSD1 | c.3895_3896del p.K1299Efs*14 | Frame Shift Del (DEL) | VAF 8/34 reads (24%) | called by mutect2, pindel, varscan2
- NSMAF | c.1041A>C p.E347D | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, varscan2
- NSMAF | c.970G>T p.D324Y | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- NUP155 | c.3890C>A p.P1297H (on ENST00000231498 / NM_153485.3; = p.P1238H on NM_004298.4) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by mutect2, varscan2
- OR4K13 | c.616C>A p.L206M | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.531); called by muse, mutect2, varscan2
- OR5V1 | c.542T>C p.I181T | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- OSBPL3 | c.1651G>A p.E551K | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHB11 | c.1696C>T p.Q566* | Nonsense Mutation (SNP) | VAF 40/334 reads (12%) | called by muse, varscan2
- PDZD2 | c.192del p.E65Kfs*21 | Frame Shift Del (DEL) | VAF 28/93 reads (30%) | called by mutect2, pindel, varscan2
- PHF24 | c.703dup p.D235Gfs*3 | Frame Shift Ins (INS) | VAF 10/67 reads (15%) | called by mutect2, pindel, varscan2
- PLEC | c.11593G>T p.A3865S (on ENST00000322810 / NM_201380.4; = p.A3755S on NM_000445.5) | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- POGZ | c.3192dup p.F1065Vfs*2 | Frame Shift Ins (INS) | VAF 5/20 reads (25%) | called by mutect2, pindel, varscan2
- PTER | c.737A>G p.Q246R | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2
- PUDP | c.238A>C p.T80P | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- R3HDM2 | c.1049T>C p.F350S | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- RFX7 | c.1505G>T p.R502M (on ENST00000559447 / NM_001368074.1; = p.R599M on NM_022841.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- RIMS1 | c.1756dup p.T586Nfs*6 | Frame Shift Ins (INS) | VAF 5/28 reads (18%) | called by mutect2, pindel, varscan2
- RPL10 | c.7C>A p.R3S | Missense Mutation (SNP) | VAF 4/52 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.405); called by muse, mutect2
- SEMA3B | c.409C>T p.H137Y | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- SERPINE3 | c.375del p.C126Afs*64 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- SEZ6L2 | c.2165G>A p.G722D (on ENST00000308713 / NM_001114099.3; = p.G652D on NM_012410.4) | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SLC22A3 | c.877del p.R293Vfs*3 | Frame Shift Del (DEL) | VAF 11/76 reads (14%) | called by mutect2, pindel, varscan2
- SLC22A3 | c.1382A>G p.Y461C | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SLC35E1 | c.629del p.K210Rfs*25 | Frame Shift Del (DEL) | VAF 11/46 reads (24%) | called by mutect2, pindel, varscan2
- SLCO2A1 | c.1606C>A p.L536I | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- SORCS2 | c.2219del p.C740Lfs*73 | Frame Shift Del (DEL) | VAF 13/49 reads (27%) | called by mutect2, pindel, varscan2
- SPIRE1 | c.1241C>T p.T414I (on ENST00000409402 / NM_001128626.2; = p.T400I on NM_020148.3) | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.646); called by muse, mutect2, varscan2
- SSX7 | c.354G>C p.E118D | Missense Mutation (SNP) | VAF 69/301 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- ST6GAL1 | c.679del p.T227Lfs*5 | Frame Shift Del (DEL) | VAF 13/71 reads (18%) | called by mutect2, pindel, varscan2
- STAT5B | c.1423_1425del p.D475del | In Frame Del (DEL) | VAF 4/36 reads (11%) | called by mutect2, pindel, varscan2
- TLN1 | c.2449G>A p.G817S | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- TMEM131 | c.3976del p.L1326Sfs*26 | Frame Shift Del (DEL) | VAF 10/69 reads (14%) | called by mutect2, pindel, varscan2
- TREH | c.155_158del p.K52Sfs*9 | Frame Shift Del (DEL) | VAF 15/94 reads (16%) | called by mutect2, pindel, varscan2
- TSHZ2 | c.2447T>C p.V816A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- TTLL11 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 25/131 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- TTN | c.50561G>A p.S16854N (on ENST00000591111; = p.S9430N on NM_003319.4) | Missense Mutation (SNP) | VAF 12/42 reads (29%) | PolyPhen benign (0.009); called by muse, mutect2, varscan2
- UBA6 | c.897del p.F299Lfs*8 | Frame Shift Del (DEL) | VAF 12/55 reads (22%) | called by mutect2, varscan2
- USP9X | c.4338dup p.F1447Ifs*6 | Frame Shift Ins (INS) | VAF 18/89 reads (20%) | called by mutect2, pindel, varscan2
- VIRMA | c.2163del p.F721Lfs*11 | Frame Shift Del (DEL) | VAF 10/50 reads (20%) | called by mutect2, varscan2
- VPS13A | c.6235A>C p.I2079L | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- VPS26A | c.721G>A p.V241I | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.379); called by muse, mutect2, varscan2
- VPS8 | c.2204G>A p.G735D (on ENST00000625842 / NM_001349294.1; = p.G733D on NM_015303.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- WBP1 | c.125A>G p.H42R | Missense Mutation (SNP) | VAF 6/55 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- ZBTB20 | c.2075del p.P692Lfs*43 (on ENST00000474710 / NM_001164342.2; = p.P619Lfs*43 on NM_015642.6 and 4 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 10/58 reads (17%) | called by mutect2, pindel, varscan2
- ZBTB25 | c.30_32del p.L11del | In Frame Del (DEL) | VAF 8/70 reads (11%) | called by pindel, varscan2
- ZGLP1 | c.307C>G p.Q103E | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- ZNF540 | c.1130A>G p.H377R | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2, varscan2
- ZNF592 | c.718dup p.E240Gfs*10 | Frame Shift Ins (INS) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- ZNF628 | c.2423G>T p.G808V | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.556); called by muse, mutect2, varscan2
- ZNF680 | c.580C>T p.L194F | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- ABCA4 | c.5007A>T p.S1669= | Silent (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- AFAP1L2 | c.1824G>T p.L608= | Silent (SNP) | VAF 31/165 reads (19%) | catalogued as COSV58412649; called by muse, mutect2, varscan2
- AP1B1 | c.1806C>T p.S602= | Silent (SNP) | VAF 10/86 reads (12%) | catalogued as rs376097084; called by muse, mutect2, varscan2
- AP1G2 | c.831T>C p.T277= | Silent (SNP) | VAF 6/30 reads (20%) | called by muse, varscan2
- AP2A1 | c.2415G>A p.L805= | Silent (SNP) | VAF 14/64 reads (22%) | catalogued as rs1304768208, COSV100571084; called by muse, varscan2
- ARID4B | c.846G>A p.E282= | Silent (SNP) | VAF 4/35 reads (11%) | called by muse, mutect2
- CABIN1 | c.4167G>A p.T1389= | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs374980657; called by mutect2, varscan2
- CHTF18 | c.798T>C p.P266= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs1310026318; called by muse, mutect2, varscan2
- COG3 | c.1743A>G p.S581= | Silent (SNP) | VAF 8/42 reads (19%) | called by muse, mutect2, varscan2
- DTX4 | c.735C>A p.T245= | Silent (SNP) | VAF 13/55 reads (24%) | called by muse, mutect2, varscan2
- DYNC1H1 | c.4674G>A p.K1558= | Silent (SNP) | VAF 10/39 reads (26%) | catalogued as rs755597231, COSV64136767; called by muse, mutect2, varscan2
- ERC2 | c.1344G>A p.S448= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as rs374815779; called by muse, mutect2, varscan2
- FZD10 | c.957C>T p.F319= | Silent (SNP) | VAF 26/94 reads (28%) | catalogued as COSV57471897; called by muse, mutect2, varscan2
- GABRD | c.876G>A p.T292= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as rs747305505; called by muse, mutect2, varscan2
- GGA3 | c.1665G>A p.T555= (on ENST00000537686 / NM_138619.4; = p.T522= on NM_014001.5) | Silent (SNP) | VAF 27/205 reads (13%) | catalogued as rs1035275071; called by muse, mutect2, varscan2
- GPANK1 | c.402G>A p.G134= | Silent (SNP) | VAF 10/35 reads (29%) | catalogued as rs746340580; called by muse, mutect2, varscan2
- GUCD1 | c.702C>A p.L234= | Silent (SNP) | VAF 12/102 reads (12%) | called by muse, mutect2, varscan2
- H2AP | c.351C>T p.D117= | Silent (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- IPO7 | c.63C>A p.A21= | Silent (SNP) | VAF 21/87 reads (24%) | called by muse, mutect2, varscan2
- IREB2 | c.576G>A p.S192= | Silent (SNP) | VAF 17/101 reads (17%) | catalogued as rs779584145; called by muse, mutect2, varscan2
- KIF27 | c.1710G>A p.G570= | Silent (SNP) | VAF 10/162 reads (6%) | catalogued as rs1353133839; called by muse, mutect2
- NOTCH2 | c.3165C>T p.Y1055= | Silent (SNP) | VAF 9/39 reads (23%) | called by muse, mutect2, varscan2
- PASK | c.3447G>A p.S1149= | Silent (SNP) | VAF 10/48 reads (21%) | catalogued as rs747034071; called by muse, mutect2, varscan2
- PCDHA13 | c.2037G>A p.S679= | Silent (SNP) | VAF 44/140 reads (31%) | catalogued as rs1223534357, COSV56474514; called by muse, mutect2, varscan2
- PCDHGA12 | c.1908C>T p.D636= | Silent (SNP) | VAF 43/187 reads (23%) | catalogued as rs1312138743; called by muse, mutect2, varscan2
- PCSK6 | c.2421C>T p.C807= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as rs558140987, COSV61857469; called by muse, mutect2, varscan2
- PDPR | c.1527C>T p.I509= | Silent (SNP) | VAF 14/119 reads (12%) | catalogued as rs372598022; called by muse, mutect2, varscan2
- PEAK3 | c.567C>T p.R189= | Silent (SNP) | VAF 9/54 reads (17%) | catalogued as rs75893730; called by muse, mutect2, varscan2
- PFKP | c.921C>T p.H307= | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as rs752473997; called by muse, mutect2, varscan2
- PIGW | c.1077A>G p.V359= | Silent (SNP) | VAF 10/76 reads (13%) | called by muse, mutect2, varscan2
- PITX2 | c.54G>A p.Q18= | Silent (SNP) | VAF 8/28 reads (29%) | called by mutect2, varscan2
- PKD1 | c.243G>A p.A81= | Silent (SNP) | VAF 51/309 reads (17%) | catalogued as rs1213595516; called by muse, mutect2, varscan2
- PKHD1 | c.9216G>A p.A3072= | Silent (SNP) | VAF 10/33 reads (30%) | catalogued as rs764734730; called by muse, mutect2, varscan2
- PNLIPRP1 | c.1383G>A p.L461= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs782004465; called by muse, mutect2, varscan2
- RHBDL3 | c.639C>T p.R213= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs754556557; called by muse, mutect2, varscan2
- RPRD2 | c.4143A>G p.P1381= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs779634430; called by mutect2, varscan2
- SCLT1 | c.477C>T p.D159= | Silent (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- SERAC1 | c.1131T>C p.D377= | Silent (SNP) | VAF 12/61 reads (20%) | catalogued as COSV100894809; called by mutect2, varscan2
- SLC12A7 | c.2991C>T p.S997= | Silent (SNP) | VAF 23/115 reads (20%) | called by muse, mutect2, varscan2
- SLC5A4 | c.1965C>T p.H655= | Silent (SNP) | VAF 17/71 reads (24%) | catalogued as rs780626840, COSV56673839; called by muse, mutect2, varscan2
- SREBF1 | c.2298C>T p.P766= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs768671095, COSV99888438; called by muse, mutect2, varscan2
- TCF3 | c.594C>T p.T198= | Silent (SNP) | VAF 9/36 reads (25%) | catalogued as rs745492073; called by muse, mutect2, varscan2
- TICRR | c.4443C>T p.N1481= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs760061593, COSV51537281; called by muse, mutect2, varscan2
- TMEM132D | c.471C>T p.D157= | Silent (SNP) | VAF 27/83 reads (33%) | catalogued as rs139627769; called by muse, mutect2, varscan2
- TNPO1 | c.1932A>G p.P644= | Silent (SNP) | VAF 15/56 reads (27%) | called by muse, mutect2, varscan2
- TNRC6A | c.5322C>T p.S1774= | Silent (SNP) | VAF 26/95 reads (27%) | called by muse, mutect2, varscan2
- ZNF324 | c.102C>T p.F34= | Silent (SNP) | VAF 6/34 reads (18%) | catalogued as rs147573504; called by muse, mutect2, varscan2
- ZNF74 | c.1371G>A p.A457= | Silent (SNP) | VAF 12/63 reads (19%) | catalogued as rs779029121; called by muse, mutect2, varscan2
- A1CF | c.100-6611G>A | Intron (SNP) | VAF 7/28 reads (25%) | called by muse, mutect2, varscan2
- MGAM | c.4618+5599G>A | Intron (SNP) | VAF 18/102 reads (18%) | catalogued as rs373367889; called by muse, mutect2, varscan2
- SNORD114-28 | n.49C>T | RNA (SNP) | VAF 36/149 reads (24%) | catalogued as rs371507233; called by muse, mutect2, varscan2
